Surgical pathology report (de-identified scan), TCGA case TCGA-YZ-A984, project TCGA-UVM (Uveal Melanoma), tissue source site The Ohio State University, specimen TCGA-YZ-A984-01A (Primary Tumor).

[page 1 of 3]
Facility

Name

Result Information

Status

Edited

Provider Status

Ordered

Observation Date and Time

Entry Date

Result Narrative

(NOTE)

Surgical Pathology Report

Patient Name:

Accession #:

Med. Rec #:

Submitting Physician:

--- Clinical History ---

Melanoma left eye.

ICD O.3

Melanoma, epithelioid & spindle
cell mixed 8770/3

Site ④ Choroid C69.3

JW 3/12/14

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

A. Left eye, enucleation:

- Malignant melanoma, mixed with predominantly spindle cell type.

B. Vortex vein, left eye, biopsy:

- No evidence of malignant melanoma.

All controls show appropriate reactivity.

The immunohistochemical and/or in situ hybridization tests reported here, except for those addressing HER-2/neu overexpression, have been developed and their performance characteristics determined by the

at the
have nor do they have FDA approval.

and are not required to

---Electronically Signed By---

---Addendum Report---

[page 2 of 3]
Addendum

Status: Signed Out

Unchanged.

Microscopic examination was performed on H&E and PAS stained sections.

Cytogenetics Report:

Status: Signed Out

Cytogenetics Case Number:

[REDACTED]

Karyotype:

46,XX,t(3;6)(q27;q15)[4]/46,XX[16]

Interpretation:

This is a tumor from the left eye of a patient with ocular melanoma. Cytogenetic analysis of this sample shows an abnormal clone of cells with a translocation between chromosomes 3 and 6. The most common recurring abnormalities seen in uveal melanomas are nonrandom changes of chromosomes 1, 3, 6 and 8. More specifically, deletions of 1p, monosomy for chromosome 3, gains of 6p, losses of 6q, and i(8q). Structural rearrangements of chromosomes 3 are rare in uveal melanomas, most often seen with unbalanced translocations resulting in deletions of 3q. The significance of the rearrangement of chromosomes 3 and 6 in this sample is not known.

Ref: K. Sisley "Tumors of the Eye", in Cancer Cytogenetics, 3rd Edition, S Heim & F Mitelman eds, Wiley-Blackwell, 2009, 621-640

Electronically Signed Out By

MD

---MICROSCOPIC:---

Specimen A shows sections of a globe with a large choroidal tumor (1.5cm diameter and 1.4 cm height) composed predominantly of a cohesive spindle cell proliferation. Focal areas with cells having an epithelioid appearance are also noted. Mitotic figures are rare. The tumor is partially pigmented. The ciliary body is not involved by the tumor. Also, scleral or extrascleral extension is not identified. The optic nerve is not observed

[page 3 of 3]
on the sections taken. These findings are consistent with a spindle cell malignant melanoma arising from the choroid.
Specimen B shows a vascular channel not involved by malignant melanoma.

---SPECIMEN(S) RECEIVED:---

A: Eye, enucleation
B: Neuropathology, BX, NOS

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number.

A. The specimen is designated "enucleated left eye" and consists of a 2.8 x 2.4 x 2.6 cm globe with a clear cornea measuring 1.1 x 1.0 cm in diameter. The optic nerve stump is 0.2 cm in length. The specimen is trisected revealing a brown-black, partially fragmented mass measuring 1.5 cm in maximum diameter and 1.4 cm in maximum height. The mass is in the inferior aspect of the posterior chamber. RS 2

Summary of Cassettes: A1, lower calotte with tumor; A2, central eye slab

B. The specimen is designated "vortex vein left eye" and consists of a 0.2 x 0.1 x 0.05 cm portion of tan-red soft tissue. TE 1

Lab Use Only: Job ID [REDACTED]

Gross description by:

Patient Release Status:

This result is not viewable by the patient.

Patient Care Team

	Relationship	Specialty	Notifications	Start	End
[REDACTED]		Family Medicine			
[REDACTED]		Dermatology			
MD					
[REDACTED]		Medical Oncology			
DO					
[REDACTED]		Surgical Oncology			
[REDACTED]		Endocrinology,			
MD		Diabetes &			
		Metabolism			
[REDACTED]		OB/GYN			
[REDACTED]		Ophthalmology			
MD					

Procedures with Linked Chargeables

Chargeable

CPT Code
88305

Criteria	hu 1/8/14	Yes	No

Source: NCI Genomic Data Commons file 7187a1e1-7da1-46ab-9eb3-682fe353617c (TCGA-YZ-A984.ECC9EDD8-CE51-49B8-9B3A-52D69920080F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).